Somatic mutation profile of tumor specimen TCGA-OR-A5JJ-01A (aliquot TCGA-OR-A5JJ-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JJ, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 65.9 years (24,082 days).
Specimen TCGA-OR-A5JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2a13de2-cb01-410f-a005-80e6dc54eec0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JJ-10A (Blood Derived Normal), aliquot TCGA-OR-A5JJ-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/575b5989-b13d-4a9b-82f7-01d4845bf606

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 71/87 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>C p.C275S | Missense Mutation (SNP) | VAF 40/51 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ASXL3 | c.3193C>T p.R1065W | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52481019, COSV99322995; called by muse, mutect2, varscan2
- DAXX | c.1085G>C p.R362P | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56468687; called by muse, mutect2
- HMCN1 | c.7420G>A p.V2474I | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs771535572; called by muse, mutect2, varscan2
- ZMPSTE24 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.371); catalogued as rs748601004; called by muse, mutect2, varscan2
- ASPG | c.1343A>C p.E448A | Missense Mutation (SNP) | VAF 36/594 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2
- ATP6V0A4 | c.2010G>C p.Q670H | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CRYBG3 | c.6785C>T p.P2262L | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX27 | c.1962G>C p.Q654H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EPHB4 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GTPBP10 | c.181_182del p.R61Vfs*17 | Frame Shift Del (DEL) | VAF 51/162 reads (31%) | called by mutect2, pindel, varscan2
- MIEF2 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPRD | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- CGN | c.2448G>A p.Q816= | Silent (SNP) | VAF 51/68 reads (75%) | called by muse, mutect2, varscan2
- ERGIC3 | c.19C>T p.L7= | Silent (SNP) | VAF 53/128 reads (41%) | called by muse, mutect2, varscan2
- ESPL1 | c.411C>T p.P137= | Silent (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
